CCDI case PBCKKC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/77aee4c6-cb17-4366-9488-bb37f9f3807f

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,122 days).

Biospecimens (2 samples)
- Sample 0DU3KJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU3KR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
